Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2J, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2J-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

CELE ICD-O-3
Sarcoma, pleomorphic
undifferentiated 8805/3
(8805/3)
path Code to 8805/3
Sarcoma, spindle cell
8801/3
Site - Retroperitoneum
C48.0

Clinical Diagnosis & History:

with h/o ovarian thecoma remote now with large pelvic mass.
Core needle biopsy => spindle cell neoplasm; pelvic sarcoma.

Specimens Submitted:

1: SP: Pelvic sarcoma

DIAGNOSIS:

1. SOFT TISSUE, PELVIC SARCOMA, EXCISION: AKA: UPS
- SPINDLE CELL SARCOMA, SEE COMMENT.
- TUMOR MEASURES 19.3 CM GREATEST DIMENSION, SHOWS ABOUT 30% NECROSIS,
AND FOCALLY EXTENDS TO UNDESIGNATED INKED MARGIN.
- PORTION OF URETER IS INCLUDED IN THE SPECIMEN.

COMMENT: TUMOR CELLS ARE FOCALLY POSITIVE FOR AE1/AE3, BCL-2, CD10, AND
CD99 AND NEGATIVE FOR CD34, ER, PR, CD117, INHIBIN, CALRETININ, AND EMA.
MORPHOLOGIC FEATURES AND CYTOKERATIN STAINING STRONGLY SUGGEST SYNOVIAL
SARCOMA, AND RT-PCR FOR SYT-SSX IS IN PROGRESS. AT ANY RATE, HIGH MITOTIC
RATE AND EXTENSIVE NECROSIS POINT TO A HIGH GRADE TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	CD34	
	BCL2	
	CD99	
	ER-C	
	PR-C	
	CD117	
	AE1:AE3	

** Continued on next page **

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Page 2 of 2

INH
CALR
EMA
CD10
NEG CONT
IMM RECUT
NEG CONT
IMM RECUT

Gross Description:

1) The specimen is received fresh, labeled "Pelvic sarcoma" and consists of an unoriented 19.3 x 18.7 x 13.3 cm firm tan-white tumor mass, with focal congested areas and areas of degenerative change/necrosis (constituting about 20 to 30% of the mass), weighing 2,255 gm. The surface of the mass appears smooth and covered by a thin membrane. There are also two staple lines, the larger measuring 10.5 x 0.5 cm, which is inked blue and lies 0.2 cm from the tumor at its closest point. The other staple line measures 3.9 x 0.2 cm, is inked red and lies 0.2 cm from the tumor mass at its closest point. The staple line also contains a 1.5 x 0.3 x 0.2 cm long tubular structure, possible blood vessel, the end of which is shaved. In addition there is a solid cylindrical protrusion of soft tissue attached to another aspect measuring 2 x 0.9 x 0.4 cm, which is also shaved. The tumor is photographed. Tissue is submitted for TPS. Representative sections are submitted.

Summary of sections:

TM1tumor to blue inked staple line
TM2tumor to red inked staple line
T--tumor
Runinvolved tissue

Summary of Sections:

Part 1: SP: Pelvic sarcoma

Block	Sect.	Site	PCs
1	r		1
15	t		15
2	tm1		2
2	tm2		2

** End of Report **

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Spindle Cell Sarcoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Spindle cell Sarcoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The tumor morphologically shows a high grade spindle cell sarcoma. There is no discrepancy noted. Although a possibility of synovial sarcoma was received, attempts at RT-PCR were unsuccessful in confirming it. The tumor is best classified as an Undifferentiated Spindle cell Sarcoma, high grade.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 804c5eee-91b3-4376-abf2-2bc69525526c (TCGA-DX-AB2J.81C9432A-3629-49A2-9C8C-DFAE3A9F5FA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).